FM case AD5407 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bladder.
https://portal.gdc.cancer.gov/cases/b16be7a8-1e85-4cfc-bf12-8bf166063ebd

Male, 33.5 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the bladder; primary biopsied or resected from the bladder. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
